Somatic mutation profile of tumor specimen TCGA-BT-A3PH-01A (aliquot TCGA-BT-A3PH-01A-11D-A21Z-08) from TCGA case TCGA-BT-A3PH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.7 years (28,030 days).
Specimen TCGA-BT-A3PH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8172fb7-85e3-4b9c-a413-9e57528d13a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A3PH-10A (Blood Derived Normal), aliquot TCGA-BT-A3PH-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21969bf1-75f4-440d-b3ec-c3ad90ea1414

The open-access MAF lists 524 somatic variants for this specimen: 394 protein-altering or splice-affecting, 115 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 338, Silent 115, Nonsense Mutation 42, Intron 6, Splice Region 4, Splice Site 4, Frame Shift Del 4, 3'Flank 3, 5'UTR 2, Frame Shift Ins 2, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as rs139016696, CM1310362, COSV57463432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 216/238 reads (91%) | catalogued as rs1567847905, CM1110584, COSV62191872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 82/213 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 19/22 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.2646G>C p.E882D (on ENST00000404938 / NM_001163941.2; = p.E437D on NM_178559.6) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV51702924; called by muse, mutect2, varscan2
- ABHD16A | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1248310839, COSV65442529; called by muse, mutect2, varscan2
- ABI3BP | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as COSV52528002, COSV99427266; called by muse, mutect2, varscan2
- ADAM12 | c.423C>T p.L141= | Splice Region (SNP) | VAF 38/113 reads (34%) | catalogued as COSV64102415; called by muse, mutect2, varscan2
- ADCY2 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57858574; called by muse, mutect2, varscan2
- ADCY9 | c.3170G>C p.G1057A | Missense Mutation (SNP) | VAF 185/223 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV53571413; called by muse, mutect2, varscan2
- ADGRL1 | c.882G>C p.Q294H (on ENST00000340736 / NM_001008701.3; = p.Q289H on NM_014921.5) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61563548; called by muse, mutect2, varscan2
- ADGRV1 | c.3143G>A p.R1048K | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV67978232; called by muse, mutect2, varscan2
- ADGRV1 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV67978235; called by muse, mutect2, varscan2
- AFF4 | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV54791377; called by muse, mutect2, varscan2
- AGAP1 | c.2069A>G p.E690G (on ENST00000304032 / NM_001037131.3; = p.E637G on NM_014914.5) | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58317100; called by muse, mutect2, varscan2
- AGBL1 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV66848452; called by mutect2, varscan2
- AGO1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64594653; called by muse, mutect2, varscan2
- AKAP3 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1203883271, COSV50537757; called by muse, mutect2, varscan2
- AKAP9 | c.7858G>A p.E2620K (on ENST00000359028; = p.E2596K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV62338489, COSV62356557; called by muse, mutect2, varscan2
- ALDH16A1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as rs781770831, COSV53192575; called by muse, mutect2, varscan2
- ALPI | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55013373; called by muse, mutect2, varscan2
- ANKRD11 | c.2556C>G p.F852L | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); catalogued as COSV56354574; called by muse, mutect2, varscan2
- ANP32B | c.89A>T p.N30I | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV59586007; called by muse, mutect2, varscan2
- AP001781.2 | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); catalogued as COSV52786219; called by muse, mutect2, varscan2
- AP2M1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 269/554 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV53046995; called by muse, varscan2
- ARID1A | c.6103G>T p.E2035* | Nonsense Mutation (SNP) | VAF 57/172 reads (33%) | catalogued as COSV61389491; called by muse, mutect2, varscan2
- ASH1L | c.6020G>A p.R2007Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.046); catalogued as rs764160439, COSV64205364; called by muse, mutect2, varscan2
- ASNSD1 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 70/83 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53622900; called by muse, mutect2, varscan2
- ASRGL1 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100077944, COSV57123576; called by muse, mutect2, varscan2
- ATG2A | c.5459C>A p.S1820Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65965794; called by muse, mutect2, varscan2
- ATM | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 78/104 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV53725558, COSV53774616; called by muse, mutect2, varscan2
- ATP10A | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as rs766840564, COSV63513338; called by muse, mutect2, varscan2
- ATRNL1 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61796828; called by muse, mutect2, varscan2
- ATXN2 | c.2656C>G p.Q886E (on ENST00000550104; = p.Q726E on NM_002973.4) | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV66481209; called by muse, mutect2, varscan2
- BARHL1 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV55036903; called by muse, mutect2, varscan2
- BAZ1A | c.4330G>C p.E1444Q | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV62408956; called by muse, mutect2, varscan2
- BCAT2 | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV60271713; called by muse, mutect2, varscan2
- BCO1 | c.1005C>G p.F335L | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as COSV50727995; called by muse, mutect2, varscan2
- BDP1 | c.7354C>T p.P2452S | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs759761156, COSV100703381, COSV62428822; called by muse, mutect2, varscan2
- BIRC6 | c.8296C>G p.L2766V | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV70195466; called by muse, mutect2, varscan2
- BIRC6 | c.10882G>C p.D3628H | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70195470, COSV70195838; called by muse, mutect2, varscan2
- BLM | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61921669, COSV61928406; called by muse, mutect2, varscan2
- BPI | c.765G>T p.M255I (on ENST00000262865; = p.M251I on NM_001725.3) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV53403835; called by muse, mutect2, varscan2
- BRCA1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 95/99 reads (96%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as rs730881473, CM128922, COSV58783876, COSV58789484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf90 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV52949371; called by muse, mutect2, varscan2
- C5 | c.3927G>C p.L1309F | Missense Mutation (SNP) | VAF 112/258 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56323937; called by muse, mutect2, varscan2
- CAMK1D | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs752176853, COSV66606593; called by muse, mutect2, varscan2
- CARMIL1 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as rs546122808, COSV61513547; called by muse, mutect2, varscan2
- CCDC141 | c.4274C>T p.P1425L | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55368683; called by muse, mutect2, varscan2
- CCDC141 | c.4273C>T p.P1425S | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV55368697; called by muse, mutect2, varscan2
- CCDC178 | c.2463G>A p.M821I (on ENST00000383096 / NM_001105528.3; = p.M783I on NM_198995.3) | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs1465141540, COSV55758888; called by muse, mutect2, varscan2
- CCDC178 | c.2224C>G p.L742V (on ENST00000383096 / NM_001105528.3; = p.L704V on NM_198995.3) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55758904; called by muse, mutect2, varscan2
- CCDC198 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53601264; called by muse, mutect2, varscan2
- CCDC54 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs748093831, COSV53757969, COSV53759553; called by muse, mutect2, varscan2
- CDKN1B | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368157535; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEL | c.2203G>A p.E735K (on ENST00000673714; = p.E732K on NM_001807.6) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV60826250; called by muse, mutect2, varscan2
- CENPN | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV55141511; called by muse, mutect2, varscan2
- CEP250 | c.5106G>C p.Q1702H | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV61168172; called by muse, mutect2, varscan2
- CERKL | c.617T>C p.M206T | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768703034, COSV59203156; called by muse, mutect2, varscan2
- CETN3 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV51616800; called by muse, mutect2, varscan2
- CFAP65 | c.476G>C p.G159A (on ENST00000341552 / NM_194302.4; = p.G94A on NM_152389.4) | Missense Mutation (SNP) | VAF 94/126 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55389290; called by muse, mutect2, varscan2
- CHCHD1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs778494804, COSV65708083; called by muse, mutect2, varscan2
- CHD7 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as rs769949098, CM1410111, COSV71107134; called by muse, mutect2, varscan2
- CHST9 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV52429227, COSV99411298; called by muse, mutect2, varscan2
- CLK1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV58432286; called by muse, mutect2, varscan2
- CLN3 | c.838G>C p.E280Q (on ENST00000360019 / NM_001286104.2; = p.E304Q on NM_000086.2) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61104770; called by muse, mutect2, varscan2
- CLSPN | c.2938C>G p.L980V | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52046627; called by muse, mutect2, varscan2
- CMTM5 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV59304746; called by muse, mutect2, varscan2
- COG1 | c.1839C>G p.F613L | Missense Mutation (SNP) | VAF 62/68 reads (91%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.591); catalogued as COSV55428181; called by muse, mutect2, varscan2
- COPA | c.2823+1G>A p.X941_splice | Splice Site (SNP) | VAF 62/328 reads (19%) | catalogued as COSV54097839; called by muse, varscan2
- CPA3 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 108/188 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV56043314; called by muse, mutect2, varscan2
- CPEB4 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 130/225 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV54169423; called by muse, mutect2, varscan2
- CPSF3 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53007788, COSV53010708; called by muse, mutect2, varscan2
- CSMD2 | c.10141G>C p.G3381R | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53877701; called by muse, mutect2, varscan2
- CTSG | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 124/281 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.054); catalogued as COSV53534548; called by muse, mutect2, varscan2
- CTTN | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 159/200 reads (80%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as rs769315862, COSV57230120, COSV57234912; called by muse, mutect2, varscan2
- CYP2F1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58526650, COSV58527529; called by muse, mutect2, varscan2
- CYTH2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV57308703; called by muse, mutect2, varscan2
- DCAF12L2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.379); catalogued as COSV63580194; called by muse, mutect2, varscan2
- DCLRE1A | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 54/116 reads (47%) | catalogued as COSV63748615; called by muse, mutect2, varscan2
- DDX18 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54305326; called by muse, mutect2, varscan2
- DDX60 | c.1682C>G p.S561* | Nonsense Mutation (SNP) | VAF 33/64 reads (52%) | catalogued as COSV101190295; called by muse, mutect2, varscan2
- DENND2A | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52047373; called by muse, mutect2, varscan2
- DEPDC5 | c.3224C>G p.S1075C (on ENST00000400246; = p.S1144C on NM_014662.5) | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV56690830; called by muse, mutect2, varscan2
- DHTKD1 | c.1669C>G p.Q557E | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV53801587; called by muse, mutect2, varscan2
- DIPK2B | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 119/132 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67640820; called by muse, mutect2, varscan2
- DKK2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539488952, COSV53393778; called by muse, mutect2, varscan2
- DLGAP5 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV55961914; called by muse, mutect2, varscan2
- DNAAF3 | c.692G>T p.R231L (on ENST00000524407 / NM_001256715.2; = p.R278L on NM_178837.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV100787813, COSV61275186; called by muse, mutect2, varscan2
- DNAH1 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV70226330; called by muse, mutect2, varscan2
- DNAH17 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV67749505; called by muse, mutect2, varscan2
- DNAH3 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 72/97 reads (74%) | catalogued as COSV54542477; called by muse, mutect2, varscan2
- DOCK2 | c.4762G>A p.E1588K | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as rs944315319, COSV56941398; called by muse, mutect2, varscan2
- DOCK8 | c.5697C>G p.F1899L | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66617567; called by muse, mutect2, varscan2
- DRC1 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs149082901; called by muse, mutect2, varscan2
- E2F4 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58873136; called by muse, mutect2, varscan2
- EDNRB | c.1445G>C p.R482T (on ENST00000377211 / NM_001201397.1; = p.R392T on NM_000115.5) | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.525); catalogued as COSV57518857; called by muse, mutect2, varscan2
- EFCAB5 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV57925967; called by muse, mutect2, varscan2
- EIF3M | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV60072301; called by muse, mutect2, varscan2
- EMILIN1 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755203609, COSV66694207, COSV66694431; called by muse, mutect2, varscan2
- ENTR1 | c.221-1G>C p.X74_splice | Splice Site (SNP) | VAF 54/168 reads (32%) | catalogued as rs531168552, COSV53740579; called by muse, mutect2, varscan2
- EOMES | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 236/518 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55410972; called by muse, mutect2, varscan2
- EP300 | c.40A>C p.K14Q | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54325900; called by muse, mutect2, varscan2
- ERCC6 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1208368572, COSV63387817; called by muse, mutect2, varscan2
- ESRP1 | c.1152G>C p.Q384H | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV64407743; called by muse, mutect2, varscan2
- EVC | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs756255427, COSV53829116; called by muse, mutect2, varscan2
- EXOC1 | c.1290G>C p.K430N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV62119102, COSV62119197; called by muse, mutect2, varscan2
- EXOSC4 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60155256; called by muse, mutect2, varscan2
- EXOSC9 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54664861; called by muse, mutect2, varscan2
- FA2H | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54725158; called by muse, mutect2, varscan2
- FBN1 | c.5609G>A p.G1870E | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57309094; called by muse, mutect2, varscan2
- FBXO21 | c.1825G>C p.E609Q (on ENST00000330622 / NM_033624.3; = p.E602Q on NM_015002.3) | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.527); catalogued as COSV57971664; called by muse, mutect2, varscan2
- FKBP2 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58587503; called by muse, mutect2, varscan2
- FNDC3B | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 170/320 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.11); catalogued as COSV61037187; called by muse, varscan2
- FRAS1 | c.8323G>C p.D2775H | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV53588520; called by muse, mutect2, varscan2
- FREM2 | c.7212C>G p.I2404M | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV54828001; called by muse, mutect2, varscan2
- GABRG3 | c.1028G>A p.C343Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.699); catalogued as COSV61509878; called by muse, mutect2, varscan2
- GOLGA1 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as COSV65228419; called by muse, mutect2, varscan2
- GOLGA4 | c.6568G>C p.E2190Q | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62709149; called by muse, mutect2, varscan2
- GPA33 | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63300083; called by muse, mutect2, varscan2
- GPR101 | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 121/133 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV53237343, COSV53238038; called by muse, mutect2, varscan2
- GPR137 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57400950; called by muse, mutect2, varscan2
- GPR152 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56884977; called by muse, mutect2, varscan2
- GPR179 | c.3139G>A p.E1047K (on ENST00000621958; = p.E1046K on NM_001004334.4) | Missense Mutation (SNP) | VAF 103/112 reads (92%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs905448279; called by muse, mutect2, varscan2
- GRAMD1A | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV58765724; called by muse, varscan2
- GRPEL1 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV53826704; called by muse, mutect2, varscan2
- GUCY1B1 | c.1829G>C p.G610A | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52373563; called by muse, mutect2, varscan2
- HACD4 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV72217491, COSV72217738; called by muse, mutect2, varscan2
- HCN4 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.397); catalogued as rs747467877, COSV56081253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HELZ | c.2632G>C p.E878Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV62376314; called by muse, mutect2, varscan2
- HIVEP1 | c.2753C>G p.S918C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65098563, COSV65104361; called by muse, mutect2, varscan2
- HIVEP2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as COSV50005507; called by muse, mutect2, varscan2
- HKDC1 | c.2293C>G p.L765V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as COSV63575430; called by muse, mutect2, varscan2
- HMOX2 | c.87-1G>A p.X29_splice | Splice Site (SNP) | VAF 125/159 reads (79%) | catalogued as COSV54859394; called by muse, mutect2, varscan2
- HPS3 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56052582; called by muse, varscan2
- HPSE | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60985442; called by muse, mutect2, varscan2
- IFIT2 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 86/134 reads (64%) | catalogued as COSV51079591; called by muse, mutect2, varscan2
- INTS5 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57950268; called by muse, mutect2, varscan2
- IPO7 | c.1953C>G p.F651L | Missense Mutation (SNP) | VAF 66/72 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV63352516, COSV63352603; called by muse, mutect2, varscan2
- IPP | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV63431834; called by muse, mutect2, varscan2
- KAT14 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV66606636; called by muse, mutect2, varscan2
- KCNA5 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs139805781, COSV52908036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM6A | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65037086; called by muse, mutect2, varscan2
- KDM6A | c.3182C>G p.S1061* | Nonsense Mutation (SNP) | VAF 48/52 reads (92%) | catalogued as COSV65037520; called by muse, mutect2, varscan2
- KIAA1549 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV54305351, COSV99651675; called by muse, mutect2, varscan2
- KIF13A | c.4492C>G p.Q1498E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); catalogued as COSV52442532; called by muse, mutect2, varscan2
- KIF1B | c.1434G>A p.K478= (on ENST00000377086 / NM_001365952.1; = p.K432= on NM_015074.3) | Splice Region (SNP) | VAF 45/141 reads (32%) | catalogued as COSV55803267; called by muse, mutect2, varscan2
- KIF27 | c.2729G>C p.G910A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV52825020; called by muse, mutect2, varscan2
- KLHDC4 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.036); catalogued as rs773015431, COSV54505995; called by muse, mutect2, varscan2
- KLRG2 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV61801798; called by muse, varscan2
- KMT2C | c.7361G>C p.R2454T | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51286575, COSV51309308; called by muse, mutect2, varscan2
- KMT2C | c.6109G>C p.D2037H | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV51286681; called by muse, mutect2, varscan2
- KMT5B | c.45G>C p.R15S | Missense Mutation (SNP) | VAF 347/970 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58563652; called by muse, mutect2, varscan2
- KNDC1 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.715); catalogued as COSV58830928; called by muse, mutect2, varscan2
- KRTAP10-10 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV59951531; called by muse, mutect2, varscan2
- LAMB4 | c.3946C>T p.H1316Y | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52713150; called by muse, mutect2, varscan2
- LDHD | c.45G>C p.W15C | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV55580005; called by muse, mutect2, varscan2
- LEO1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 176/394 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs1183620857, COSV55174669; called by muse, mutect2, varscan2
- LMNB1 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs772870259, COSV54396587; called by muse, mutect2, varscan2
- LPIN2 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55236867; called by muse, mutect2, varscan2
- LRIG1 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 116/389 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs755071993, COSV56236603; called by muse, mutect2, varscan2
- LRP4 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 87/96 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66133938; called by muse, mutect2, varscan2
- LRRC66 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV100603101, COSV58631989; called by muse, mutect2, varscan2
- LYST | c.5957G>A p.R1986Q | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs529869172, COSV67703198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAN1B1 | c.2085C>G p.I695M | Missense Mutation (SNP) | VAF 140/315 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV65370917; called by muse, mutect2, varscan2
- MANEAL | c.1157C>T p.T386M (on ENST00000373045 / NM_001113482.1; = p.T164M on NM_152496.2) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs757628447, COSV61115541; called by muse, mutect2, varscan2
- MARCKS | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs1278066065, COSV64042561, COSV64042798; called by muse, mutect2, varscan2
- MAST4 | c.4039C>G p.R1347G (on ENST00000403625 / NM_001164664.2; = p.R1158G on NM_015183.3) | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55115465, COSV55134564; called by muse, mutect2, varscan2
- MDC1 | c.4814C>G p.S1605C | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64523104; called by muse, mutect2, varscan2
- MDC1 | c.3112C>G p.L1038V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV64523114; called by muse, mutect2, varscan2
- MDN1 | c.6778G>C p.E2260Q | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65517048, COSV65521672; called by muse, mutect2, varscan2
- ME1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV63837518; called by muse, mutect2, varscan2
- MFSD8 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56550309; called by muse, mutect2, varscan2
- MKI67 | c.7978G>C p.E2660Q | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.812); catalogued as COSV64072499; called by muse, mutect2, varscan2
- MKI67 | c.3990G>C p.K1330N | Missense Mutation (SNP) | VAF 145/298 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV104424636, COSV64072504; called by muse, mutect2, varscan2
- MPHOSPH10 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54905176; called by muse, mutect2, varscan2
- MPHOSPH10 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV54905181; called by muse, varscan2
- MPHOSPH10 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54905186, COSV54905696; called by muse, varscan2
- MPHOSPH8 | c.1235G>C p.R412T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64054261; called by muse, mutect2, varscan2
- MSH3 | c.2983G>C p.E995Q | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54144578; called by muse, mutect2, varscan2
- MST1 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56531992; called by muse, mutect2, varscan2
- MUC16 | c.19640C>G p.S6547C | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); catalogued as rs770100218, COSV67444017; called by muse, mutect2, varscan2
- MUC16 | c.15671G>C p.S5224T | Missense Mutation (SNP) | VAF 98/158 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV67444026; called by muse, mutect2, varscan2
- MYH15 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV56304237; called by muse, mutect2, varscan2
- MYLK3 | c.1529C>G p.S510C | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV67362509; called by muse, mutect2, varscan2
- MYO10 | c.5905C>T p.Q1969* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as rs1235238723; called by muse, mutect2, varscan2
- NDRG1 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs1483150822, COSV60482370; called by muse, mutect2, varscan2
- NDST4 | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV52108685; called by muse, mutect2, varscan2
- NEIL1 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as COSV61833239; called by muse, mutect2, varscan2
- NEK7 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 165/374 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66314135, COSV66314877; called by muse, mutect2, varscan2
- NES | c.4824G>C p.Q1608H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV63960342; called by muse, mutect2, varscan2
- NME7 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV63164791; called by muse, mutect2, varscan2
- NSD2 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56386357; called by muse, mutect2, varscan2
- NUAK1 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54600398; called by muse, mutect2, varscan2
- OBSCN | c.7666C>T p.R2556W | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs566340039, COSV52738921; called by muse, mutect2, varscan2
- OFD1 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 77/83 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV60794216; called by muse, mutect2, varscan2
- OGDHL | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs767864251, COSV65100729; called by muse, mutect2, varscan2
- OLFML3 | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.354); catalogued as rs144544470, COSV57434607; called by muse, mutect2, varscan2
- OPTC | c.528G>C p.L176= | Splice Region (SNP) | VAF 57/123 reads (46%) | catalogued as COSV65867230; called by muse, mutect2, varscan2
- OR2L3 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs267598495, COSV63454411, COSV63454586; called by muse, varscan2
- OR2M5 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV63545668; called by muse, mutect2, varscan2
- OR52I1 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 66/81 reads (81%) | SIFT tolerated (0.71); PolyPhen benign (0.049); catalogued as COSV56167415; called by muse, mutect2, varscan2
- OR5H6 | c.691C>G p.L231V (on ENST00000642105; = p.L215V on NM_001005479.2) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs768955413, COSV101051770, COSV67351009; called by muse, mutect2, varscan2
- OSBPL1A | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV60195165; called by muse, mutect2, varscan2
- P3H2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs866107570, COSV60018187; called by muse, mutect2, varscan2
- PABPC1 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV59397964; called by muse, mutect2
- PAIP1 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV59085172; called by muse, mutect2, varscan2
- PAPLN | c.2071G>A p.G691R (on ENST00000554301; = p.G664R on NM_173462.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs773393825, COSV53712897; called by muse, mutect2, varscan2
- PBRM1 | c.3394G>A p.E1132K (on ENST00000296302 / NM_001366071.2; = p.E1107K on NM_018313.5) | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.757); catalogued as COSV56260755, COSV56265618; called by muse, mutect2, varscan2
- PBRM1 | c.2299G>C p.E767Q | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV56260781; called by muse, mutect2, varscan2
- PCDH15 | c.3433C>G p.Q1145E | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as CM165385, COSV57262106; called by muse, mutect2, varscan2
- PCDHB13 | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV53392998; called by muse, mutect2, varscan2
- PCIF1 | c.819C>T p.I273= | Splice Region (SNP) | VAF 70/170 reads (41%) | catalogued as rs1334814143, COSV65026035; called by muse, mutect2, varscan2
- PCM1 | c.1391C>G p.S464C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs773727032, COSV61514537; called by muse, mutect2, varscan2
- PCNP | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54575012; called by muse, mutect2, varscan2
- PCOLCE2 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV55997514; called by muse, mutect2, varscan2
- PCSK5 | c.2049G>C p.K683N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV65083424; called by muse, mutect2, varscan2
- PDE4DIP | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs781911914, COSV57674253; called by muse, mutect2, varscan2
- PDGFRA | c.3242C>T p.S1081L | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV57264650; called by muse, mutect2, varscan2
- PHC1 | c.345C>G p.S115R | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV70417506; called by muse, mutect2, varscan2
- PHF24 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1402364683, COSV54272950; called by muse, mutect2, varscan2
- PHLPP1 | c.4268G>T p.S1423I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV53021724; called by muse, mutect2, varscan2
- PKHD1L1 | c.9292G>C p.E3098Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV65743513; called by muse, mutect2, varscan2
- PLAUR | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV55388433; called by muse, mutect2, varscan2
- PLN | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as rs758364608, COSV62645752, COSV62646598; called by muse, mutect2, varscan2
- POLM | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as COSV54241366; called by muse, mutect2, varscan2
- POLQ | c.7021C>T p.H2341Y | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769839271, COSV51745614; called by muse, mutect2, varscan2
- POLQ | c.6774C>G p.I2258M | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51745630; called by muse, mutect2, varscan2
- PON2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV56000358, COSV56001161; called by muse, mutect2, varscan2
- POU2AF1 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149278202; called by muse, mutect2, varscan2
- POU3F3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV63721146; called by muse, mutect2, varscan2
- PPM1J | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53516669; called by muse, mutect2, varscan2
- PPRC1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV53382968; called by muse, mutect2, varscan2
- PPRC1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 160/334 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.261); catalogued as COSV53382975; called by muse, mutect2, varscan2
- PRDM15 | c.3129G>C p.Q1043H | Missense Mutation (SNP) | VAF 132/301 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.936); catalogued as COSV54148763; called by muse, mutect2, varscan2
- PREP | c.23C>T p.P8L (on ENST00000369110; = p.P74L on NM_002726.5) | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs892698484, COSV64869127; called by muse, mutect2, varscan2
- PRKD2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.086); catalogued as COSV52184499; called by muse, mutect2, varscan2
- PRMT7 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV59832064; called by muse, mutect2, varscan2
- PRPH2 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 91/175 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV57836147; called by muse, mutect2, varscan2
- PTPRK | c.2750G>T p.G917V (on ENST00000368215 / NM_001291984.2; = p.G918V on NM_002844.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63891090; called by muse, mutect2, varscan2
- PTPRM | c.2379G>C p.K793N | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV59843713; called by muse, mutect2, varscan2
- PUS7 | c.1358C>G p.S453* | Nonsense Mutation (SNP) | VAF 109/241 reads (45%) | catalogued as rs1369180660; called by muse, mutect2, varscan2
- PVR | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.395); catalogued as COSV51822076; called by muse, mutect2, varscan2
- PZP | c.4307C>T p.S1436F | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs1158566092, COSV54354267; called by muse, mutect2, varscan2
- RAB38 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54711662; called by muse, mutect2, varscan2
- RAD51 | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51110953; called by muse, mutect2, varscan2
- RAI1 | c.5272G>A p.D1758N | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV55388990; called by muse, mutect2, varscan2
- RB1 | c.2594G>T p.G865V | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.09); catalogued as COSV57295616; called by muse, mutect2, varscan2
- RFX3 | c.1715G>A p.W572* | Nonsense Mutation (SNP) | VAF 66/145 reads (46%) | catalogued as COSV56526902; called by muse, mutect2, varscan2
- RGS12 | c.4003G>C p.E1335Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV58748664; called by muse, mutect2, varscan2
- RIPOR1 | c.1184C>G p.S395* (on ENST00000379312 / NM_001193522.2; = p.S391* on NM_024519.4) | Nonsense Mutation (SNP) | VAF 53/140 reads (38%) | catalogued as COSV50216933; called by muse, mutect2, varscan2
- RNF168 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV58836688; called by muse, mutect2, varscan2
- RNF182 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV70368685; called by muse, mutect2, varscan2
- RNF215 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53175378; called by muse, mutect2, varscan2
- RPL24 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 192/359 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57243936; called by muse, mutect2, varscan2
- RUFY3 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV56911110; called by muse, mutect2, varscan2
- SBNO1 | c.3150G>C p.M1050I (on ENST00000420886; = p.M1049I on NM_018183.5) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV57338807, COSV57341690; called by muse, varscan2
- SCN8A | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as rs771577480, COSV61991267; called by muse, mutect2, varscan2
- SEC11A | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs373819545; called by muse, mutect2, varscan2
- SEC14L2 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV57240087; called by muse, mutect2, varscan2
- SEMA5A | c.2187C>G p.F729L | Missense Mutation (SNP) | VAF 137/230 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV66784400; called by muse, mutect2, varscan2
- SEMA6C | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV58999879; called by muse, mutect2, varscan2
- SERINC3 | c.1159G>C p.D387H | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV54855375, COSV54855987, COSV54856226; called by muse, mutect2, varscan2
- SERTAD1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV63595968; called by muse, mutect2, varscan2
- SETD9 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV53649738; called by muse, mutect2, varscan2
- SH3BP5 | c.732G>C p.K244N | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.478); catalogued as COSV53742838; called by muse, mutect2, varscan2
- SH3RF1 | c.2469G>C p.L823F | Missense Mutation (SNP) | VAF 78/141 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs200527865, COSV52918151; called by muse, mutect2, varscan2
- SLC12A4 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100312444, COSV57925250; called by muse, mutect2, varscan2
- SLC26A6 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 188/541 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56569932; called by muse, mutect2, varscan2
- SLC32A1 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54145621, COSV54148747; called by muse, mutect2, varscan2
- SLC43A1 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV53557460; called by muse, mutect2, varscan2
- SLC6A15 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57019932, COSV57030277, COSV99881438; called by muse, mutect2, varscan2
- SLC7A1 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 100/192 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.239); catalogued as COSV66329546; called by muse, mutect2, varscan2
- SLC7A6OS | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.261); catalogued as COSV50449854; called by muse, mutect2, varscan2
- SLITRK5 | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV61520912, COSV61522600, COSV61523873; called by muse, mutect2, varscan2
- SLK | c.2734G>C p.E912Q | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59823694, COSV59829757; called by muse, mutect2, varscan2
- SMARCC2 | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57214179; called by muse, mutect2, varscan2
- SMC5 | c.2603T>C p.I868T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1334236345, COSV63191550; called by muse, mutect2, varscan2
- SMG5 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs1245185769, COSV62433935; called by muse, mutect2, varscan2
- SMG7 | c.2760G>T p.K920N | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.417); catalogued as COSV61629637; called by muse, varscan2
- SMG7 | c.3119G>A p.R1040K | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV61629645; called by muse, mutect2, varscan2
- SNX7 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV60265777; called by muse, mutect2, varscan2
- SORCS1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs370679881, COSV53857213; called by muse, mutect2, varscan2
- SOX5 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV58618035, COSV58633099; called by muse, mutect2, varscan2
- SOX5 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58618046, COSV58648980; called by muse, mutect2, varscan2
- SPECC1L | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV58656358; called by muse, mutect2, varscan2
- SPP1 | c.274G>T p.D92Y (on ENST00000395080 / NM_001040058.2; = p.D78Y on NM_000582.2) | Missense Mutation (SNP) | VAF 148/252 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52951361; called by muse, mutect2, varscan2
- SPTBN1 | c.3608G>C p.G1203A | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100442806, COSV61685415; called by muse, varscan2
- SRGAP1 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV61894282, COSV61901913; called by muse, mutect2, varscan2
- SRP68 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 92/104 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57161516, COSV57161685; called by muse, mutect2, varscan2
- SRRM2 | c.4343G>C p.R1448T | Missense Mutation (SNP) | VAF 91/115 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV57068008; called by muse, mutect2, varscan2
- SRRM2 | c.4543G>C p.E1515Q | Missense Mutation (SNP) | VAF 156/200 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV57068021; called by muse, mutect2, varscan2
- STK31 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.093); catalogued as COSV63453947; called by muse, mutect2, varscan2
- STRIP1 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874105, COSV63930293; called by muse, mutect2, varscan2
- SUN1 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61777362, COSV61778148; called by muse, varscan2
- SUPT16H | c.2718G>C p.M906I | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV52844475; called by muse, mutect2, varscan2
- SUZ12 | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV59498002; called by muse, mutect2
- SYNE2 | c.13813G>C p.E4605Q | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as rs1474495127, COSV59939379; called by muse, mutect2, varscan2
- SYNGR2 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 104/121 reads (86%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1202496399, COSV56744982; called by muse, mutect2, varscan2
- TAS2R50 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV67852016; called by muse, mutect2, varscan2
- TBX5 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV59858392, COSV59861141; called by muse, mutect2, varscan2
- TENM2 | c.3697G>A p.E1233K (on ENST00000518659 / NM_001122679.2; = p.E1001K on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.354); catalogued as COSV69122510; called by muse, mutect2, varscan2
- TERF2IP | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55612887; called by muse, mutect2, varscan2
- TESK2 | c.1154C>G p.P385R | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59149129; called by muse, mutect2, varscan2
- TEX14 | c.3966C>G p.F1322L (on ENST00000240361 / NM_001201457.2; = p.F1276L on NM_031272.5) | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV53611616; called by muse, mutect2, varscan2
- TGFB3 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53168901; called by muse, mutect2, varscan2
- THBS4 | c.1367G>C p.G456A | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1257743895, COSV63467699; called by muse, mutect2, varscan2
- TIPRL | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63207637; called by muse, mutect2, varscan2
- TMEM159 | c.29C>G p.S10* | Nonsense Mutation (SNP) | VAF 33/45 reads (73%) | catalogued as COSV51786209, COSV99238871; called by muse, mutect2, varscan2
- TNPO1 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV61520174; called by muse, mutect2, varscan2
- TONSL | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV68049275; called by muse, mutect2, varscan2
- TOP3A | c.1739C>G p.S580C | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58174837; called by muse, mutect2, varscan2
- TRIM45 | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56712439, COSV99868360; called by muse, mutect2, varscan2
- TRPM6 | c.3356G>T p.C1119F | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV62502721; called by muse, mutect2, varscan2
- TSC2 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757844109, COSV54755921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC36 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57096076; called by muse, mutect2, varscan2
- TTC7B | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV60624880, COSV60630532; called by muse, mutect2, varscan2
- TTN | c.92605G>C p.D30869H (on ENST00000591111; = p.D23445H on NM_003319.4) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | PolyPhen probably damaging (0.999); catalogued as COSV59883005; called by muse, mutect2, varscan2
- TTN | c.70022G>C p.R23341T (on ENST00000591111; = p.R15917T on NM_003319.4) | Missense Mutation (SNP) | VAF 64/87 reads (74%) | PolyPhen probably damaging (0.996); catalogued as COSV59883043; called by muse, mutect2, varscan2
- TXNIP | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV65219928; called by muse, mutect2, varscan2
- TXNIP | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV65219921; called by muse, mutect2, varscan2
- UBAP2 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs745920408, COSV62545141; called by muse, mutect2, varscan2
- UBR4 | c.7381G>A p.D2461N | Missense Mutation (SNP) | VAF 225/450 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV64382726; called by muse, mutect2, varscan2
- UGGT1 | c.3630G>C p.Q1210H | Missense Mutation (SNP) | VAF 109/447 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52132294; called by muse, mutect2, varscan2
- USP4 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.113); catalogued as rs756580275, COSV55534848; called by muse, mutect2, varscan2
- UTRN | c.7885G>A p.D2629N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV62307184; called by muse, mutect2, varscan2
- VPS18 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 106/222 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs1183238801, COSV55028806; called by muse, mutect2, varscan2
- VPS41 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV56068278, COSV99730421; called by muse, mutect2, varscan2
- VPS50 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58505651; called by muse, mutect2, varscan2
- VWA2 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.228); catalogued as rs1010942674, COSV53904848; called by muse, mutect2, varscan2
- XIRP1 | c.4804G>C p.E1602Q | Missense Mutation (SNP) | VAF 233/455 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV61136795; called by muse, mutect2, varscan2
- XIRP2 | c.5800G>A p.D1934N (on ENST00000628543; = p.D2109N on NM_152381.6) | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV54682047; called by muse, mutect2, varscan2
- ZBTB6 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV65409367; called by muse, mutect2, varscan2
- ZBTB6 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV65409371; called by muse, mutect2, varscan2
- ZCCHC14 | c.1097C>T p.S366L (on ENST00000268616; = p.S503L on NM_015144.3) | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs748819715, COSV51883599; called by muse, varscan2
- ZDHHC17 | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 130/275 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1049583566, COSV58350217; called by muse, mutect2, varscan2
- ZFR2 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV53596278; called by muse, mutect2, varscan2
- ZMYM6 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as rs759676745, COSV58183456; called by muse, mutect2, varscan2
- ZNF236 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 87/188 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53482081, COSV53482344; called by muse, mutect2, varscan2
- ZNF470 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV57967593; called by muse, mutect2, varscan2
- ZNF513 | c.1619C>A p.S540* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | catalogued as COSV52008718; called by muse, mutect2, varscan2
- ZNF599 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV61395483; called by muse, mutect2, varscan2
- ZNF623 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs776064066, COSV101513499, COSV71697078; called by muse, mutect2, varscan2
- ZNF626 | c.1434G>C p.E478D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as rs1555769214; called by muse, mutect2, varscan2
- ZNF626 | c.1266G>C p.E422D | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1555769237, COSV74128913; called by muse, mutect2, varscan2
- ZNF700 | c.1990C>G p.Q664E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV54310800; called by muse, mutect2, varscan2
- ZNF777 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as COSV56096151; called by muse, mutect2, varscan2
- ZNF781 | c.8G>C p.R3T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV62200277; called by muse, mutect2, varscan2
- ZNF800 | c.1265C>G p.S422C | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56173546; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 122/230 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV58349303; called by muse, mutect2, varscan2
- ZNF91 | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56080265; called by muse, mutect2, varscan2
- ABHD16A | c.536del p.G179Vfs*38 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- ADK | c.66-1del p.X22_splice (on ENST00000286621; = p.X5_splice on NM_001123.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 18/55 reads (33%) | called by mutect2, varscan2*
- ADK | c.67del p.E23Kfs*17 (on ENST00000286621; = p.E6Kfs*17 on NM_001123.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, varscan2*
- ARID1B | c.1988C>G p.S663* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- BAG6 | c.3518del p.P1173Lfs*? (on ENST00000676571; = p.P1126Lfs*? on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- BAZ2A | c.3409G>T p.E1137* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- BORCS6 | c.694C>G p.P232A | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C15orf39 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C7orf33 | c.179T>A p.L60* | Nonsense Mutation (SNP) | VAF 74/182 reads (41%) | called by muse, mutect2, varscan2
- CATSPERD | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 95/372 reads (26%) | called by muse, mutect2, varscan2
- CEMP1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 18/23 reads (78%) | called by muse, mutect2, varscan2
- CRLF2 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 91/112 reads (81%) | called by muse, mutect2, varscan2
- FCGBP | c.5566G>A p.E1856K | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.196); called by muse, mutect2
- GPR161 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 113/284 reads (40%) | called by muse, mutect2, varscan2
- HOOK1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 67/170 reads (39%) | called by muse, mutect2, varscan2
- IGF1R | c.2716C>T p.Q906* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- IKBKE | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 63/153 reads (41%) | called by muse, mutect2, varscan2
- ITIH1 | c.1608C>A p.F536L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM3A | c.1412dup p.V472Gfs*22 | Frame Shift Ins (INS) | VAF 35/121 reads (29%) | called by mutect2, pindel, varscan2
- KPNA4 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- MSL1 | c.1583_1593delinsC p.Q528Pfs*34 (on ENST00000398532 / NM_001365919.1; = p.Q265Pfs*34 on NM_001012241.2) | Frame Shift Del (DEL) | VAF 21/24 reads (88%) | called by pindel, varscan2*
- NAA25 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 63/151 reads (42%) | called by muse, mutect2, varscan2
- NOS3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PACS1 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- PIGG | c.1956G>A p.W652* (on ENST00000453061 / NM_001127178.3; = p.W644* on NM_017733.4) | Nonsense Mutation (SNP) | VAF 30/46 reads (65%) | called by muse, mutect2, varscan2
- PSAT1 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- RALYL | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RIMBP2 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 65/144 reads (45%) | called by muse, mutect2, varscan2
- SERTM1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- SGMS2 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 62/228 reads (27%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.4055C>G p.S1352* | Nonsense Mutation (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- SLA2 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- SLC45A4 | c.677G>A p.W226* (on ENST00000517878 / NM_001286646.2; = p.W175* on NM_001080431.2) | Nonsense Mutation (SNP) | VAF 105/210 reads (50%) | called by muse, mutect2, varscan2
- SLC8A1 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 97/235 reads (41%) | called by muse, mutect2, varscan2
- SMPD4 | c.1874C>G p.S625* (on ENST00000409031 / NM_017951.4; = p.S596* on NM_017751.4) | Nonsense Mutation (SNP) | VAF 156/244 reads (64%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by mutect2, varscan2
- TMEM185A | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by mutect2, varscan2
- TRAV40 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- TUBGCP6 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 69/188 reads (37%) | called by muse, mutect2, varscan2
- UPK1B | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 77/243 reads (32%) | called by muse, mutect2, varscan2
- ZNF322 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.263); called by mutect2, varscan2
- ZNF582 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- ZNF615 | c.103dup p.D35Gfs*38 | Frame Shift Ins (INS) | VAF 174/383 reads (45%) | called by mutect2, pindel, varscan2
- ACMSD | c.858C>T p.V286= | Silent (SNP) | VAF 308/350 reads (88%) | catalogued as rs942351549, COSV51605476; called by muse, mutect2, varscan2
- ACOX1 | c.843C>G p.V281= | Silent (SNP) | VAF 103/120 reads (86%) | catalogued as COSV53131288; called by muse, mutect2, varscan2
- ADAMTSL4 | c.3150C>T p.V1050= | Silent (SNP) | VAF 101/257 reads (39%) | catalogued as COSV54996309; called by muse, mutect2, varscan2
- ADCY5 | c.2748C>T p.L916= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as COSV59193966; called by muse, mutect2, varscan2
- ALDH16A1 | c.732G>A p.R244= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53192560; called by muse, mutect2, varscan2
- AMDHD1 | c.621C>T p.I207= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV57137685; called by muse, mutect2, varscan2
- ANKS1A | c.1449G>C p.R483= | Silent (SNP) | VAF 91/164 reads (55%) | catalogued as COSV64458749; called by muse, mutect2, varscan2
- ASXL1 | c.168C>G p.L56= | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as COSV60102975; called by muse, mutect2, varscan2
- CADM3 | c.999C>T p.I333= (on ENST00000368125 / NM_001127173.3; = p.I367= on NM_021189.5) | Silent (SNP) | VAF 84/176 reads (48%) | catalogued as rs774303512, COSV63675447; called by muse, mutect2, varscan2
- CANX | c.784C>T p.L262= | Silent (SNP) | VAF 78/150 reads (52%) | catalogued as COSV56002599; called by muse, mutect2, varscan2
- CCM2 | c.1122G>A p.V374= | Silent (SNP) | VAF 59/124 reads (48%) | catalogued as COSV51846456; called by muse, mutect2, varscan2
- CCN4 | c.1023C>T p.F341= | Silent (SNP) | VAF 68/129 reads (53%) | catalogued as COSV51529398; called by muse, mutect2, varscan2
- CCSER1 | c.756C>G p.T252= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV61406166; called by muse, mutect2, varscan2
- CD19 | c.1185C>T p.S395= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV61187757; called by muse, mutect2, varscan2
- CD247 | c.213C>G p.L71= | Silent (SNP) | VAF 73/206 reads (35%) | catalogued as COSV62976872; called by muse, mutect2
- CD47 | c.264C>T p.V88= | Silent (SNP) | VAF 68/189 reads (36%) | catalogued as rs780855506, COSV62526617; called by muse, mutect2, varscan2
- CD48 | c.55C>T p.L19= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV63565927; called by muse, mutect2, varscan2
- CD86 | c.195G>C p.L65= (on ENST00000330540 / NM_175862.5; = p.L59= on NM_006889.4) | Silent (SNP) | VAF 123/244 reads (50%) | catalogued as COSV52604992; called by muse, mutect2, varscan2
- CDK11A | c.1590G>C p.L530= (on ENST00000378633 / NM_001313896.2; = p.L527= on NM_024011.4) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV52306751; called by muse, mutect2, varscan2
- CLIP2 | c.1785G>A p.L595= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV56274168; called by muse, mutect2, varscan2
- CNTNAP5 | c.3018G>A p.T1006= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs779991769, COSV70471908; called by muse, mutect2, varscan2
- COL6A6 | c.2115G>C p.L705= | Silent (SNP) | VAF 148/271 reads (55%) | catalogued as COSV62017462; called by muse, mutect2, varscan2
- COLGALT2 | c.1047C>G p.L349= | Silent (SNP) | VAF 169/428 reads (39%) | catalogued as COSV62298529; called by muse, mutect2, varscan2
- CYBB | c.1260C>T p.L420= | Silent (SNP) | VAF 46/52 reads (88%) | catalogued as rs1186258856, COSV66084681; called by muse, mutect2, varscan2
- DEPTOR | c.495C>T p.F165= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as COSV53812416; called by muse, mutect2, varscan2
- DERL3 | c.372C>T p.L124= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs1169895417, COSV51954220; called by muse, mutect2, varscan2
- DPP10 | c.690A>G p.L230= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV59663805; called by muse, mutect2, varscan2
- EDEM2 | c.1668C>T p.L556= | Silent (SNP) | VAF 153/376 reads (41%) | catalogued as rs1277191130, COSV63259447; called by muse, mutect2, varscan2
- EIF4B | c.241C>A p.R81= | Silent (SNP) | VAF 56/200 reads (28%) | catalogued as COSV50401590; called by muse, varscan2
- EPPK1 | c.666C>T p.P222= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs782273480, COSV101599822, COSV73260789; called by muse, mutect2, varscan2
- FAT2 | c.3675C>T p.T1225= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as rs1017033452, COSV55812582; called by muse, varscan2
- FBXL8 | c.48C>T p.I16= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV50456576; called by muse, mutect2, varscan2
- FBXO2 | c.798C>T p.F266= | Silent (SNP) | VAF 175/307 reads (57%) | catalogued as rs763453911, COSV62813294; called by muse, mutect2, varscan2
- FBXO3 | c.1362G>C p.R454= | Silent (SNP) | VAF 68/80 reads (85%) | catalogued as COSV55764950; called by muse, mutect2, varscan2
- FBXW2 | c.171C>G p.L57= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV61596417; called by muse, mutect2, varscan2
- FCRL3 | c.1321C>T p.L441= | Silent (SNP) | VAF 103/248 reads (42%) | catalogued as COSV63839358; called by muse, mutect2, varscan2
- FREM1 | c.1914C>T p.D638= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs754363171, COSV66517610; called by muse, mutect2, varscan2
- GEMIN5 | c.4407C>A p.L1469= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV53557911; called by muse, mutect2, varscan2
- GLB1L3 | c.1602C>T p.I534= | Silent (SNP) | VAF 35/42 reads (83%) | catalogued as COSV68392386; called by muse, mutect2, varscan2
- GNL1 | c.1542C>T p.L514= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs985080364, COSV64920666; called by muse, mutect2, varscan2
- GNPTG | c.405G>A p.Q135= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as rs763335225, COSV50189767; called by muse, mutect2, varscan2
- GPR179 | c.2859G>A p.R953= (on ENST00000621958; = p.R952= on NM_001004334.4) | Silent (SNP) | VAF 21/23 reads (91%) | called by muse, mutect2, varscan2
- GPR179 | c.2373G>A p.L791= (on ENST00000621958; = p.L790= on NM_001004334.4) | Silent (SNP) | VAF 20/23 reads (87%) | called by muse, mutect2, varscan2
- HDAC9 | c.1740G>A p.T580= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV67766560; called by muse, mutect2
- HEPACAM2 | c.876C>T p.I292= (on ENST00000394468 / NM_001039372.4; = p.I280= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV59057732; called by muse, mutect2, varscan2
- HLA-DOA | c.9C>G p.L3= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57713510; called by muse, mutect2, varscan2
- HTRA2 | c.12G>A p.P4= | Silent (SNP) | VAF 74/168 reads (44%) | catalogued as COSV51206105, COSV99239704; called by muse, mutect2, varscan2
- HTT | c.5946C>G p.L1982= | Silent (SNP) | VAF 61/119 reads (51%) | catalogued as COSV61857255; called by muse, mutect2, varscan2
- INTS5 | c.2655C>T p.L885= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV57950258; called by muse, mutect2, varscan2
- JAK3 | c.555G>A p.L185= | Silent (SNP) | VAF 53/89 reads (60%) | catalogued as COSV71685471; called by muse, mutect2, varscan2
- KCNB2 | c.675A>G p.G225= | Silent (SNP) | VAF 61/135 reads (45%) | catalogued as COSV73048846; called by muse, mutect2, varscan2
- KCNMB3 | c.657G>A p.L219= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV99840323; called by muse, mutect2, varscan2
- KDM3A | c.2421C>T p.A807= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1452861725, COSV57217910; called by muse, mutect2, varscan2
- KRBA1 | c.495G>A p.R165= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs778221369, COSV55439875; called by muse, mutect2, varscan2
- LAMA1 | c.7413C>G p.L2471= | Silent (SNP) | VAF 104/227 reads (46%) | catalogued as COSV67531905; called by muse, mutect2, varscan2
- LDLRAD2 | c.504C>T p.F168= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV60827449; called by muse, mutect2, varscan2
- LMNA | c.456C>G p.L152= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV61541944; called by muse, mutect2, varscan2
- LMTK3 | c.3573C>T p.L1191= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54309508; called by muse, mutect2, varscan2
- LRFN2 | c.1146C>G p.L382= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV57823692; called by muse, mutect2, varscan2
- LRRC41 | c.594C>G p.L198= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as rs749270377, COSV58438860; called by muse, mutect2, varscan2
- LRRC8C | c.1242G>A p.L414= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as COSV64995122; called by muse, mutect2, varscan2
- MAPK14 | c.168C>T p.S56= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV57694592; called by muse, mutect2, varscan2
- MGAT5B | c.594C>T p.L198= | Silent (SNP) | VAF 22/23 reads (96%) | catalogued as rs1201941668, COSV56924917; called by muse, mutect2, varscan2
- MOGS | c.1071G>A p.L357= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as COSV51968090; called by muse, mutect2, varscan2
- MYCBP2 | c.11838C>G p.V3946= (on ENST00000357337; = p.V3984= on NM_015057.5) | Silent (SNP) | VAF 66/129 reads (51%) | catalogued as COSV62009991; called by muse, mutect2, varscan2
- MYO1C | c.1698C>A p.L566= (on ENST00000648651 / NM_001080779.2; = p.L531= on NM_033375.5) | Silent (SNP) | VAF 54/62 reads (87%) | catalogued as COSV62998315; called by muse, mutect2, varscan2
- MZF1 | c.2079G>A p.R693= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1374285555, COSV53040569; called by muse, mutect2, varscan2
- NDUFA7 | c.21C>T p.L7= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1407656456; called by muse, mutect2, varscan2
- NKX2-5 | c.438G>A p.S146= | Silent (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- NLRP8 | c.1308C>T p.P436= | Silent (SNP) | VAF 77/129 reads (60%) | catalogued as COSV52583234; called by muse, mutect2, varscan2
- NPC1 | c.2559G>C p.L853= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV52576192; called by muse, mutect2, varscan2
- NT5DC2 | c.762G>C p.L254= | Silent (SNP) | VAF 60/186 reads (32%) | catalogued as COSV58732006; called by muse, mutect2, varscan2
- NTSR2 | c.843G>A p.V281= | Silent (SNP) | VAF 80/173 reads (46%) | catalogued as COSV60990371; called by muse, mutect2, varscan2
- NUP188 | c.4704C>T p.F1568= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV65330101; called by muse, mutect2, varscan2
- NUP93 | c.705G>A p.L235= | Silent (SNP) | VAF 87/180 reads (48%) | catalogued as COSV57428547; called by muse, mutect2, varscan2
- OSMR | c.555G>A p.Q185= | Silent (SNP) | VAF 72/105 reads (69%) | catalogued as COSV57080818; called by muse, mutect2, varscan2
- PCDHA5 | c.1335C>A p.A445= | Silent (SNP) | VAF 97/177 reads (55%) | catalogued as rs1554129143, COSV65349244; called by muse, mutect2, varscan2
- PDLIM5 | c.1689C>T p.C563= | Silent (SNP) | VAF 63/93 reads (68%) | catalogued as COSV58745050; called by muse, mutect2, varscan2
- PPIL1 | c.303C>T p.A101= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV65472320; called by muse, mutect2, varscan2
- PRKD2 | c.2217G>A p.V739= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as COSV52184487; called by muse, mutect2, varscan2
- PRPF40B | c.1227C>T p.L409= (on ENST00000380281; = p.L403= on NM_012272.3) | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs371066831; called by muse, mutect2, varscan2
- PRPF6 | c.2311C>T p.L771= | Silent (SNP) | VAF 114/216 reads (53%) | catalogued as rs1041029673, COSV53865665; called by muse, mutect2, varscan2
- PRR30 | c.657G>A p.L219= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs1217925043, COSV53204438; called by muse, mutect2, varscan2
- PRR4 | c.384C>T p.P128= | Silent (SNP) | VAF 86/184 reads (47%) | catalogued as COSV57391874, COSV57392057; called by muse, mutect2, varscan2
- PUS10 | c.1422C>T p.F474= | Silent (SNP) | VAF 134/287 reads (47%) | catalogued as rs770289093, COSV57450458; called by muse, mutect2, varscan2
- RAET1E | c.447C>G p.L149= | Silent (SNP) | VAF 96/171 reads (56%) | catalogued as COSV61722081; called by muse, varscan2
- RASGRF2 | c.2676G>C p.G892= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV54122711, COSV99429788; called by muse, mutect2, varscan2
- RFX5 | c.705C>T p.L235= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV51837972; called by muse, varscan2
- RNF208 | c.561C>G p.P187= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV61286235; called by muse, mutect2, varscan2
- RNF208 | c.84C>A p.L28= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1173688839, COSV61286240; called by muse, mutect2, varscan2
- RNF40 | c.1005G>A p.L335= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV61213449; called by muse, mutect2, varscan2
- RTL5 | c.885C>A p.A295= | Silent (SNP) | VAF 149/157 reads (95%) | catalogued as COSV65452359; called by muse, mutect2, varscan2
- RUFY3 | c.645G>C p.L215= | Silent (SNP) | VAF 81/160 reads (51%) | catalogued as COSV56911131; called by muse, mutect2, varscan2
- SDC3 | c.1131G>A p.K377= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV59578369; called by muse, mutect2, varscan2
- SELENOF | c.24G>C p.P8= | Silent (SNP) | VAF 63/151 reads (42%) | catalogued as COSV59354722, COSV59356866; called by muse, mutect2, varscan2
- SEMA4F | c.1998C>T p.F666= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV60281875; called by muse, mutect2, varscan2
- SFN | c.24G>A p.Q8= | Silent (SNP) | VAF 89/192 reads (46%) | catalogued as COSV59432936; called by muse, mutect2, varscan2
- SLC12A3 | c.279C>G p.L93= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV52632382; called by muse, mutect2, varscan2
- SLC18A3 | c.462G>A p.P154= | Silent (SNP) | VAF 55/231 reads (24%) | catalogued as COSV60320028; called by muse, mutect2, varscan2
- SLC2A9 | c.477C>T p.L159= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV53316391; called by muse, mutect2, varscan2
- STRIP1 | c.1815G>A p.V605= | Silent (SNP) | VAF 65/158 reads (41%) | catalogued as COSV63930297; called by muse, mutect2, varscan2
- SYNE2 | c.9825C>T p.L3275= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as rs1470499754, COSV59939372; called by muse, mutect2, varscan2
- TCF20 | c.1695G>A p.Q565= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV59488213; called by muse, mutect2, varscan2
- TEP1 | c.345C>T p.L115= | Silent (SNP) | VAF 77/200 reads (39%) | catalogued as COSV52987933; called by muse, mutect2, varscan2
- TLN2 | c.2679G>C p.L893= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV60885439, COSV60886623; called by muse, mutect2, varscan2
- TMEM54 | c.24G>C p.L8= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV61275468, COSV61275897; called by muse, mutect2, varscan2
- TNNT1 | c.774C>T p.I258= | Silent (SNP) | VAF 60/96 reads (63%) | catalogued as rs890470817, COSV52570302; called by muse, mutect2, varscan2
- TNXB | c.5109C>T p.G1703= (on ENST00000647633; = p.G1456= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as rs751200506, COSV64472893; called by muse, mutect2, varscan2
- TUBGCP6 | c.723C>G p.L241= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV50536441; called by muse, mutect2, varscan2
- UBR5 | c.2406C>T p.F802= | Silent (SNP) | VAF 123/230 reads (53%) | catalogued as COSV55279832; called by muse, mutect2, varscan2
- UFD1 | c.282C>G p.L94= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV54250149; called by muse, mutect2, varscan2
- UPF1 | c.2142G>C p.R714= (on ENST00000599848 / NM_001297549.2; = p.R703= on NM_002911.4) | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV53193782; called by muse, mutect2, varscan2
- VPS13D | c.3852C>G p.L1284= | Silent (SNP) | VAF 145/297 reads (49%) | catalogued as rs1248631403, COSV50621560; called by muse, mutect2, varscan2
- YIPF2 | c.909C>T p.I303= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs151256467, COSV99450312; called by muse, mutect2, varscan2
- ZNF616 | c.1671C>T p.V557= | Silent (SNP) | VAF 64/106 reads (60%) | catalogued as COSV57509470; called by muse, mutect2, varscan2
- ADGRL2 | c.3626-731C>T | Intron (SNP) | VAF 92/212 reads (43%) | catalogued as COSV54651671, COSV54682723; called by muse, mutect2, varscan2
- CDC40 | c.*2G>C | 3'UTR (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100309455; called by muse, mutect2, varscan2
- CTBP2 | c.59-2314G>A | Intron (SNP) | VAF 157/260 reads (60%) | catalogued as COSV58332443; called by muse, mutect2, varscan2
- FAM153CP | chr5:178056003 G>C | 3'Flank (SNP) | VAF 49/131 reads (37%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1298G>A | RNA (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- HRAS | c.450+132_450+141del | Intron (DEL) | VAF 16/24 reads (67%) | called by mutect2, varscan2
- LHX6 | chr9:122228725 C>T | 5'Flank (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5609G>A | Intron (SNP) | VAF 49/103 reads (48%) | catalogued as COSV56220824; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120874 C>T | 3'Flank (SNP) | VAF 42/48 reads (88%) | called by mutect2, varscan2
- PDE4DIP | c.637-7584A>G | Intron (SNP) | VAF 141/338 reads (42%) | catalogued as rs587632003, COSV57674278; called by muse, mutect2, varscan2
- RAB26 | chr16:2155071 G>C | 3'Flank (SNP) | VAF 55/67 reads (82%) | called by muse, mutect2, varscan2
- TGIF1 | c.-196A>G | 5'UTR (SNP) | VAF 20/33 reads (61%) | catalogued as COSV57906573; called by muse, mutect2, varscan2
- TMBIM6 | c.-31+550G>A | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as rs1049749495, COSV57278519, COSV99920664; called by muse, mutect2, varscan2
- VN1R10P | n.606C>G | RNA (SNP) | VAF 82/155 reads (53%) | called by muse, mutect2, varscan2
- ZNF436 | c.-92G>A | 5'UTR (SNP) | VAF 37/93 reads (40%) | catalogued as rs765274083, COSV58357977; called by muse, mutect2, varscan2
